Somatic mutation profile of tumor specimen TARGET-40-NAAGKC-01A (aliquot TARGET-40-NAAGKC-01A-01D) from TARGET case TARGET-40-NAAGKC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.2 years (3,708 days).
Specimen TARGET-40-NAAGKC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a57267-c5db-4b90-a863-8fcbd2f0e41b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKC-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKC-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a3d2c25-512d-47f9-b105-b6f0e0aced28

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 3, Silent 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5M1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1452831673, COSV99841134; called by muse, mutect2, varscan2
- CCDC158 | c.2706G>C p.R902S | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as rs937136612, COSV66356844; called by muse, mutect2
- GATAD2B | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV64083107; called by muse, mutect2, varscan2
- GDAP1L1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs750011361; called by muse, mutect2, varscan2
- ZNF735 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV70035211; called by muse, mutect2, varscan2
- CCDC174 | c.783C>A p.N261K | Missense Mutation (SNP) | VAF 107/178 reads (60%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLMN | c.1460A>G p.D487G | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAPK1 | c.2789T>C p.V930A | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH17 | c.8896G>A p.V2966M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- EHBP1 | c.3507G>T p.E1169D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ETNK2 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.088); called by muse, mutect2
- FAM131B | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GBP4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- HYAL4 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 49/254 reads (19%) | called by muse, mutect2, varscan2
- MEGF10 | c.1446C>A p.C482* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- OBSCN | c.23222T>C p.L7741P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, varscan2
- RIMS1 | c.2654C>A p.P885Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.592); called by muse, mutect2
- TNPO1 | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- WDR97 | c.2834C>A p.S945Y | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF749 | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF2K | c.645C>T p.I215= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs780591039, COSV53780225; called by muse, mutect2, varscan2
- MYO18B | c.2718C>T p.D906= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- SEC14L5 | c.1887G>A p.P629= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs779997505; called by muse, mutect2, varscan2
- AMBP | c.*6G>C | 3'UTR (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- GRM8 | c.727+48380C>T | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as rs1414578610, COSV58808115; called by muse, mutect2
